Surgical pathology report (de-identified scan), TCGA case TCGA-CN-4726, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-4726-01A (Primary Tumor).

[page 1 of 4]
PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Left buccal cancer.

PROCEDURE: Neck dissection.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

E-record history: [REDACTED] male with a large buccal tumor (T3 N2B squamous cell carcinoma) which involves almost the entire buccal mucosa but does not extend into the alveolus of either mandible or maxilla. There is an associated metastatic adenopathy.

FINAL DIAGNOSIS:

PART 1: BUCCAL MUCOSA, LEFT, SUBMANDIBULAR GLAND, LYMPH NODES, LEFT LEVEL 1, EXCISION AND SELECTIVE NECK DISSECTION –

- A. INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED WITH INFILTRATIVE BORDER (4.5 CM), EXTENDING INTO PERIOSTEUM (see comment).
- B. ANGIOLYMPHATIC AND PERINEURAL INVASION PRESENT.
- C. TUMOR PRESENT AT DEEP, SUPERIOR BUCCAL, AND INFERIOR GINGIVAL MARGINS; TUMOR <0.1 CM FROM INFERIOR BUCCAL MARGIN.
- D. METASTATIC SQUAMOUS CELL CARCINOMA IN SOFT TISSUE EXTENDING INTO SUBMANDIBULAR GLAND (4.5 CM).
- E. METASTATIC SQUAMOUS CELL CARCINOMA IN THREE OF THREE LYMPH NODES WITH EXTRACAPSULAR SPREAD (3/3) (LARGEST METASTATIC FOCUS: 1.8 CM).
- F. PATHOLOGIC STAGE: pT3, N2b.

PART 2: LYMPH NODES, LEFT LEVELS 2 AND 3, SELECTIVE DISSECTION –
METASTATIC SQUAMOUS CELL CARCINOMA IN TWO OF THREE LYMPH NODES (2/3) (LARGEST METASTATIC FOCUS: 0.8 CM).

PART 3: LYMPH NODE, LEFT NECK LEVEL 2, EXCISION –
ONE LYMPH NODE, NO TUMOR PRESENT (0/1).

PART 4: LYMPH NODES, LEFT NECK LEVEL 4, SELECTIVE DISSECTION –
METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OF SEVEN LYMPH NODES (1/7) (METASTATIC FOCUS: 0.4 CM).

[page 2 of 4]
Pathology Report

COMMENT:

Ancillary studies will be performed and reported as an addendum.

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in four parts:

Part 1 is received fresh from identified with the patient's name with initials [REDACTED] and labeled as "left buccal mucosa, left mandibular periosteum, left submandibular gland and left level 1". It measures overall 10.5 x 7.5 x 5.0 cm and consists of a resection of the buccal mucosa with tumor (4.5 x 3.5 x 2.5 cm), soft tissue with 4.5 x 1.8 cm piece of mandibular periosteum and submandibular soft tissue with submandibular gland (2.5 x 2.8 x 1.8 cm), multiple lymph nodes.

The tumor (4.5 x 3.5 x 2.5 cm) has an ulcerated necrotic surface and on sectioning comes within 0.4-cm from the superior buccal mucosal resection margin, 0.3-cm from the inferior buccal mucosal resection margin, abuts to the deep tumorous section margin and is 4.8 cm from the inferior gingival mucosal resection margin.

The periosteum is overlying and second ulcerated, spatially distinct mass (4.5 x 2.5 x 2.8-cm) which appears grossly extend into the submandibular gland. The soft tissue from the level 1 contains additional three lymph nodes, all replaced by tumor.

Gross photographs are taken.

Tissue from the buccal tumor, normal mucosa and tissue from the positive lymph node are frozen for [REDACTED].

Ink code: Blue - buccal soft tissue and mucosal resection margin, green - periosteum, black - gingival resection margin

Section code:

1A and 1B - anterior and posterior superomedial buccal mucosa resection margin, en face

1C - tumor with deep soft tissue resection margin

1D and 1E - additional sections of the tumor with the deep resection margin

1F and 1G - tumor and inferior buccal mucosal resection margin, perpendicular

1H and 1I - secondary mass and overlying periosteum

1J - inferolateral gingival resection margin, en face

1K - submandibular gland with secondary tumor extension

1L - second largest mass, random sections

1M to 1O - lymph nodes, level 1

Part 2 is received fresh, identified with the patient's name with initials [REDACTED] and labeled as "left side levels 2 and 3". It consists of a piece of fibrofatty tissue (5.5 x 3.5 x 1.0-cm) containing three lymph nodes (0.6 to 2.6-cm). Two largest lymph nodes are grossly involved by the tumor.

Section code:

2A and 2B - one lymph node in each, bisected

2C - one lymph node

Part 3 is received fresh, identified with the patient's name with initials [REDACTED] and labeled as "left neck level 2". It consists of a piece of fibrofatty tissue containing one 0.9-cm lymph node. The specimen is submitted in toto in cassette 3A.

Part 4 is received fresh, identified with the patient's name with initials [REDACTED] labeled as "left neck level 4". It consists of a piece of fibrofatty tissue containing multiple lymph nodes (0.5 to 1.8-cm). The largest lymph node is grossly involved the tumor.

[page 3 of 4]
Pathology Report

Section code:

4A - largest lymph node, bisected

4B - remaining lymph nodes

INTRAOPERATIVE CONSULTATION:

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of [REDACTED] to a maximum of [REDACTED].

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE: Resection: Mucosal and soft tissue resection

TUMOR SITE: Oral Cavity

TUMOR SIZE: Greatest dimension: 4.5 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: G2

PRIMARY TUMOR (pT): pT3

REGIONAL LYMPH NODES (pN): pN2b

Number of regional lymph nodes examined: 14

Number of regional lymph nodes involved: 6

Extra-capsular extension of nodal tumor: Present

DISTANT METASTASIS (pM): pMX

MARGINS: Margin(s) involved by tumor

Location(s): deep, superomedial, inferior gingival

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Present

PERINEURAL INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS: Other: SOFT TISSUE DEPOSIT INVOLVING SUBMANDIBULAR

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Left Buccal Mucosa, Left Mandibular Periosteum, Left Submandibular Gland, Left Level 1

Taken: [REDACTED]

[page 4 of 4]
Pathology Report

Stain/cnt	Block
H&E x 1	A
H&E x 1	B
H&E Recut x 1	C
IHPV x 1	C
cmef x 1	C
IEGFR x 1	C
IBNKNC x 1	C
IBNKNC x 1	C
IBNKNC x 1	C
IBNKNC x 1	C
IBNKNC x 1	C
IBNKNC x 1	C
H&E x 1	C
P16 x 1	C
V-EGFR x 1	C
H&E x 1	D
H&E x 1	E
H&E x 1	F
H&E x 1	G
H&E x 1	H
H&E x 1	I
H&E x 1	J
H&E x 1	K
H&E x 1	L
H&E x 1	M
H&E x 1	N
H&E x 1	O
PHSU x 2	(none)

Part 2: Left Sides Levels 2 and 3

Taken: [REDACTED]

Stain/cnt	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C

Part 3: Left Neck Level 2

Taken: [REDACTED]

Stain/cnt	Block
H&E x 1	A

Part 4: Left Neck Level 4

Taken: [REDACTED]

Stain/cnt	Block
H&E x 1	A
H&E x 1	B

ICD-9 Diagnosis Codes: {None Entered}

Source: NCI Genomic Data Commons file 5391c25f-25ca-41ed-926e-bc10f799ee34 (TCGA-CN-4726.73A88D18-8158-474C-B506-A4BA478D8CA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).